TCGA case TCGA-CQ-5324 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: University Health Network, Toronto. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78e67b26-c473-449f-95e7-c4d11f066d5b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 59.7 years (21,803 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N2a; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic stage: Stage III; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,593 days (4.4 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 24; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 0 days; Treatment outcome: No Measurable Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,207 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,593 days (4.4 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 43; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 2006.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CQ-5324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-CQ-5324-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent neutrophil infiltration: 5.
  Slide TCGA-CQ-5324-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 82; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent neutrophil infiltration: 1.
- Sample TCGA-CQ-5324-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CQ-5324-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Floor of mouth; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 4; Alcohol history documented: No.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,593 days; disease-specific survival: no event (censored), 1,593 days; progression-free interval: no event (censored), 1,593 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CQ-5324-01A-01D-1682-01): tumor purity 0.68, ploidy 2.02, whole-genome doublings 0.
